Somatic mutation profile of cancer-model specimen HCM-BROD-0449-C34-85M (2D Modified Conditionally Reprogrammed Cells, passage 11; aliquot HCM-BROD-0449-C34-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-BROD-0449-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.3 years (26,423 days).
Specimen HCM-BROD-0449-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b595f2ec-ee05-4d40-8984-65b16e82da40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0449-C34-10B (Blood Derived Normal), aliquot HCM-BROD-0449-C34-10B-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d4b8515-2f37-42bf-8840-f9516bb84aca

The open-access MAF lists 209 somatic variants for this specimen: 155 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 47, Nonsense Mutation 13, Intron 4, Frame Shift Del 3, RNA 2, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 595/596 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 97/97 reads (100%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55666071; called by muse, mutect2, varscan2
- ADGRB3 | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 182/392 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV65393597; called by muse, mutect2, varscan2
- ANKRD17 | c.6960A>G p.S2320= | Splice Region (SNP) | VAF 77/160 reads (48%) | catalogued as rs766144116; called by muse, mutect2, varscan2
- APCS | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 167/341 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54819307; called by muse, mutect2, varscan2
- ARPP21 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 366/367 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs376713321, COSV51793709; called by muse, mutect2, varscan2
- ATG9A | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 354/559 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769517669; called by muse, mutect2, varscan2
- C1orf115 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 195/396 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs754626511; called by muse, mutect2, varscan2
- CCDC39 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV99866648; called by muse, mutect2, varscan2
- CLCA4 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV55367081; called by muse, mutect2, varscan2
- CPEB4 | c.1883C>A p.A628E | Missense Mutation (SNP) | VAF 130/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99437595; called by muse, mutect2, varscan2
- CTCFL | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54770144; called by muse, mutect2, varscan2
- CUTA | c.170C>G p.S57W (on ENST00000488034 / NM_001014840.2; = p.S34W on NM_015921.3) | Missense Mutation (SNP) | VAF 444/1032 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV53378281; called by muse, mutect2, varscan2
- DGKB | c.1991T>A p.I664K | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337055; called by muse, mutect2, varscan2
- DNAH11 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs760400011, COSV100180719; called by muse, mutect2, varscan2
- EBF2 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV68776356; called by muse, mutect2, varscan2
- EML1 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772174519, COSV51746088; called by muse, mutect2, varscan2
- EVX2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 194/614 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57962699; called by muse, mutect2, varscan2
- FYN | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 366/654 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57615055; called by muse, mutect2, varscan2
- GALNT13 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 184/275 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222537, COSV67215488; called by muse, mutect2, varscan2
- GFM1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 41/325 reads (13%) | catalogued as rs771890880, COSV99963100; called by muse, mutect2, varscan2
- GLYATL2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 210/210 reads (100%) | catalogued as COSV54849551; called by muse, mutect2, varscan2
- GRB14 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 118/189 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1240225857; called by muse, mutect2
- HOXD9 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 238/766 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs1185539872; called by muse, mutect2, varscan2
- HUWE1 | c.10447A>C p.T3483P | Missense Mutation (SNP) | VAF 369/369 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53338931; called by muse, mutect2, varscan2
- IGKV3-15 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs745796620; called by mutect2, varscan2
- KCNA1 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 218/800 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230111; called by muse, mutect2, varscan2
- KCNC4 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 420/809 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs369670720; called by muse, mutect2, varscan2
- KLHL1 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100918162, COSV64777211; called by muse, mutect2, varscan2
- KLHL1 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs144761752; called by muse, mutect2, varscan2
- LAMB3 | c.1699T>C p.C567R | Missense Mutation (SNP) | VAF 326/1197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61917442; called by muse, mutect2
- LIPC | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 326/328 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540524619; called by muse, mutect2, varscan2
- MACF1 | c.4261G>C p.E1421Q | Missense Mutation (SNP) | VAF 152/152 reads (100%) | catalogued as COSV58359132; called by muse, mutect2, varscan2
- MAML3 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV101558283; called by muse, mutect2, varscan2
- MELTF | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 373/671 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs762942426, COSV56382344, COSV99586326; called by muse, mutect2, varscan2
- METTL6 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 383/383 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540802719; called by muse, mutect2, varscan2
- MMP16 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54170667; called by muse, mutect2, varscan2
- NCAM2 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 241/404 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as rs1396341533; called by muse, mutect2, varscan2
- NIM1K | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771487658; called by muse, mutect2, varscan2
- NLRP8 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 192/317 reads (61%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201546502, COSV52586071; called by muse, mutect2, varscan2
- NPHS2 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1406733643; called by muse, mutect2
- OPCML | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 304/306 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1442244590, COSV100099132, COSV59412062; called by muse, mutect2, varscan2
- OR52B6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs1168098948, COSV61448074; called by muse, mutect2
- PAQR4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 582/582 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as rs748157967; called by muse, mutect2, varscan2
- PCDH12 | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 317/317 reads (100%) | catalogued as COSV99190108; called by muse, mutect2, varscan2
- PCDHGB7 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 374/375 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.378); catalogued as rs755798236, COSV99548670; called by muse, mutect2, varscan2
- PPHLN1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as rs781307689; called by muse, mutect2, varscan2
- PPM1D | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 227/480 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100011095; called by muse, mutect2, varscan2
- PYGO2 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 487/946 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.133); catalogued as rs866373283, COSV63757621; called by muse, mutect2, varscan2
- RGS5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV58352000; called by muse, mutect2, varscan2
- RPN1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 510/947 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56190268; called by muse, mutect2, varscan2
- SCN2A | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1228890159, COSV51849978; called by muse, mutect2, varscan2
- SLC25A42 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 296/679 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs202000540; called by muse, mutect2, varscan2
- SP140 | c.2149C>A p.H717N | Missense Mutation (SNP) | VAF 184/274 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59453840; called by muse, varscan2
- SPAG5 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199294215; called by muse, mutect2, varscan2
- TBXT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 528/528 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775012230, COSV51616284; called by muse, mutect2, varscan2
- TEAD4 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 730/731 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs371373848; called by muse, mutect2, varscan2
- TM9SF2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV64507136; called by muse, mutect2, varscan2
- TRIM69 | c.1075G>C p.E359Q (on ENST00000329464 / NM_182985.5; = p.E200Q on NM_080745.5) | Missense Mutation (SNP) | VAF 354/355 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs776968166; called by muse, mutect2, varscan2
- TTN | c.69490G>A p.V23164I (on ENST00000591111; = p.V15740I on NM_003319.4) | Missense Mutation (SNP) | VAF 225/362 reads (62%) | PolyPhen probably damaging (0.991); catalogued as rs371306826; called by muse, mutect2, varscan2
- TTN | c.58141C>G p.R19381G (on ENST00000591111; = p.R11957G on NM_003319.4) | Missense Mutation (SNP) | VAF 213/347 reads (61%) | PolyPhen probably damaging (0.998); catalogued as COSV59879754; called by muse, mutect2, varscan2
- XDH | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 177/561 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101052175; called by muse, mutect2, varscan2
- ZDBF2 | c.616A>G p.S206G | Missense Mutation (SNP) | VAF 225/360 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1475184233; called by muse, mutect2, varscan2
- ZFHX4 | c.7915G>A p.A2639T | Missense Mutation (SNP) | VAF 120/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99266465; called by muse, mutect2, varscan2
- ZFHX4 | c.8807T>C p.M2936T | Missense Mutation (SNP) | VAF 219/352 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51445952; called by muse, mutect2, varscan2
- ZNF423 | c.1230G>T p.Q410H (on ENST00000563137 / NM_001379286.1; = p.Q402H on NM_015069.4) | Missense Mutation (SNP) | VAF 431/431 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV52178927; called by muse, mutect2, varscan2
- ZNF471 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 127/225 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57290083; called by muse, mutect2, varscan2
- ZNF705A | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 89/443 reads (20%) | catalogued as COSV63733572; called by muse, mutect2, varscan2
- ADCY8 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 247/829 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ADRA2A | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 299/300 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL645922.1 | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 302/651 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- B4GALT6 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 67/68 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- BPNT2 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 560/1038 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- BRWD3 | c.3045G>T p.M1015I | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C4orf50 | c.3G>A p.M1? (on ENST00000324058; = p.M1233I on NM_001364689.1 and 1 other RefSeq transcript) | Translation Start Site (SNP) | VAF 174/175 reads (99%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP8 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 136/226 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CATSPERG | c.2888A>G p.Y963C | Missense Mutation (SNP) | VAF 434/713 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.1896C>G p.I632M | Missense Mutation (SNP) | VAF 249/500 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNRIP1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2
- CUL3 | c.1831T>G p.Y611D | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- DLEC1 | c.3213G>T p.Q1071H | Missense Mutation (SNP) | VAF 295/296 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- DOCK8 | c.1205_1208del p.A402Gfs*4 | Frame Shift Del (DEL) | VAF 114/280 reads (41%) | called by mutect2, pindel, varscan2
- DOP1B | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGLN2 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 277/698 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FANCD2 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 255/257 reads (99%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FBN2 | c.741G>C p.W247C | Missense Mutation (SNP) | VAF 310/311 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL6 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 276/590 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FOLH1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 263/272 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRG2 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 248/301 reads (82%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FRG2C | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 117/1134 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- GALC | c.1628C>G p.A543G | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- GJA10 | c.785A>T p.K262M | Missense Mutation (SNP) | VAF 274/558 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GLYATL2 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPC5 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GTPBP3 | c.1253T>A p.V418E | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, varscan2
- GUCY2D | c.2035G>C p.V679L | Missense Mutation (SNP) | VAF 374/374 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HOXC5 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 682/682 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IDO2 | c.252C>A p.H84Q (on ENST00000389060; = p.H97Q on NM_194294.2) | Missense Mutation (SNP) | VAF 230/511 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IGFN1 | c.2383G>T p.D795Y (on ENST00000295591 / NM_001367841.1; = p.D3252Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 288/592 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- IGKV1D-16 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 200/336 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IRF8 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 284/285 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ITGA11 | c.370del p.L124Sfs*66 | Frame Shift Del (DEL) | VAF 247/350 reads (71%) | called by mutect2, pindel, varscan2
- LMTK3 | c.2900del p.P967Qfs*13 | Frame Shift Del (DEL) | VAF 92/862 reads (11%) | called by mutect2, pindel, varscan2
- LRP2 | c.9861G>T p.L3287F | Missense Mutation (SNP) | VAF 215/308 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- LRP2 | c.7965T>A p.C2655* | Nonsense Mutation (SNP) | VAF 75/249 reads (30%) | called by muse, mutect2, varscan2
- MAGEB1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MGA | c.4490C>G p.S1497* | Nonsense Mutation (SNP) | VAF 310/310 reads (100%) | called by muse, mutect2, varscan2
- MPO | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 338/708 reads (48%) | called by muse, mutect2, varscan2
- MRPL40 | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 178/341 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSC | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 373/864 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- MTBP | c.2222T>C p.L741P | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH7 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO15A | c.1301A>T p.E434V | Missense Mutation (SNP) | VAF 518/1548 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1F | c.2640G>C p.K880N | Missense Mutation (SNP) | VAF 481/481 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCOA2 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 217/470 reads (46%) | called by muse, mutect2, varscan2
- NEB | c.4996G>T p.E1666* | Nonsense Mutation (SNP) | VAF 183/316 reads (58%) | called by muse, mutect2, varscan2
- NIN | c.5696A>G p.N1899S (on ENST00000382041 / NM_182946.1; = p.N1186S on NM_016350.4) | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLE1 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 340/692 reads (49%) | called by muse, mutect2, varscan2
- NPHP3 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NSD3 | c.3450C>G p.I1150M | Missense Mutation (SNP) | VAF 82/619 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, varscan2
- OR2AK2 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- OR5T1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.58); called by mutect2, varscan2
- PHF20L1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 232/681 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3CA | c.2011T>G p.L671V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.991C>G p.H331D | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R14D | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PRDM13 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 224/495 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRKD1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 333/334 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAD54L2 | c.1043A>G p.N348S | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RANBP17 | c.2210A>G p.Y737C | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RGS22 | c.935_952del p.C312_S317del | In Frame Del (DEL) | VAF 54/467 reads (12%) | called by mutect2, pindel
- RPEL1 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 414/414 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCML2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 254/255 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SEC63 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 173/353 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SERPINB3 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B4 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 264/540 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, varscan2
- SMCR8 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 383/1089 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM267 | c.428T>A p.F143Y | Missense Mutation (SNP) | VAF 206/633 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- TNKS | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 605/606 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNN | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 393/843 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TNR | c.3193dup p.R1065Kfs*5 | Frame Shift Ins (INS) | VAF 219/579 reads (38%) | called by mutect2, pindel, varscan2
- TOP3A | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRAJ41 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 195/195 reads (100%) | called by muse, mutect2, varscan2
- TRHR | c.1183T>A p.F395I | Missense Mutation (SNP) | VAF 119/395 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC4 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- TSPOAP1 | c.5414A>G p.D1805G | Missense Mutation (SNP) | VAF 218/499 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.32456C>A p.P10819Q (on ENST00000591111; = p.P9892Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/273 reads (60%) | PolyPhen benign (0.134); called by muse, mutect2, varscan2
- UBR5 | c.4787C>G p.A1596G | Missense Mutation (SNP) | VAF 70/603 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VIRMA | c.5294C>T p.P1765L | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WDR26 | c.1723T>G p.L575V (on ENST00000414423 / NM_001379403.1; = p.L475V on NM_025160.7) | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ZFHX4 | c.7083C>A p.Y2361* | Nonsense Mutation (SNP) | VAF 164/321 reads (51%) | called by muse, mutect2, varscan2
- ZNF407 | c.5678T>C p.L1893P | Missense Mutation (SNP) | VAF 15/500 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF441 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ZNF707 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 1236/1811 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- ACSM4 | c.429G>T p.P143= | Silent (SNP) | VAF 373/374 reads (100%) | catalogued as COSV101257044; called by muse, mutect2, varscan2
- ADRM1 | c.382C>T p.L128= | Silent (SNP) | VAF 333/335 reads (99%) | catalogued as COSV53351989, COSV53366612; called by muse, varscan2
- ATP13A1 | c.1227G>T p.G409= | Silent (SNP) | VAF 429/431 reads (100%) | called by muse, mutect2, varscan2
- BMP6 | c.1428G>T p.P476= | Silent (SNP) | VAF 230/482 reads (48%) | catalogued as COSV99307230; called by muse, varscan2
- CABS1 | c.822T>A p.A274= | Silent (SNP) | VAF 218/218 reads (100%) | called by muse, mutect2, varscan2
- CDH20 | c.2355G>A p.R785= | Silent (SNP) | VAF 464/464 reads (100%) | called by muse, mutect2, varscan2
- CYFIP2 | c.2874A>G p.L958= (on ENST00000616178 / NM_001291722.2; = p.L933= on NM_014376.4) | Silent (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- DAO | c.868C>A p.R290= | Silent (SNP) | VAF 191/351 reads (54%) | catalogued as COSV57321304; called by muse, mutect2, varscan2
- DDI2 | c.339A>G p.P113= | Silent (SNP) | VAF 278/279 reads (100%) | called by muse, mutect2, varscan2
- FLG | c.10524A>G p.E3508= | Silent (SNP) | VAF 268/595 reads (45%) | catalogued as rs567642253; called by muse, mutect2, varscan2
- FRG2 | c.594C>A p.I198= | Silent (SNP) | VAF 253/304 reads (83%) | called by muse, mutect2, varscan2
- GABRA6 | c.453C>A p.T151= | Silent (SNP) | VAF 170/170 reads (100%) | called by muse, mutect2, varscan2
- GJC3 | c.36G>A p.E12= | Silent (SNP) | VAF 322/322 reads (100%) | catalogued as rs569274106; called by muse, mutect2, varscan2
- HOXD1 | c.54C>G p.G18= | Silent (SNP) | VAF 93/785 reads (12%) | catalogued as rs1360550000; called by muse, mutect2, varscan2
- IGKV3-15 | c.60A>T p.G20= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs561717275; called by mutect2, varscan2
- INTS8 | c.2577A>T p.A859= | Silent (SNP) | VAF 179/358 reads (50%) | catalogued as rs942716871; called by muse, mutect2, varscan2
- ITGB6 | c.1962G>T p.A654= | Silent (SNP) | VAF 242/363 reads (67%) | catalogued as rs201818641, COSV51796580; called by muse, mutect2, varscan2
- KPRP | c.126G>A p.E42= | Silent (SNP) | VAF 74/776 reads (10%) | called by muse, mutect2
- LRRC4B | c.1125C>T p.V375= | Silent (SNP) | VAF 460/808 reads (57%) | catalogued as COSV65349527; called by muse, mutect2, varscan2
- MDH1 | c.627T>G p.V209= | Silent (SNP) | VAF 124/365 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.9099C>T p.Y3033= | Silent (SNP) | VAF 211/931 reads (23%) | catalogued as rs371187428; called by muse, mutect2, varscan2
- OR10G4 | c.864C>G p.T288= | Silent (SNP) | VAF 241/241 reads (100%) | called by muse, mutect2, varscan2
- OR4D9 | c.714C>T p.S238= | Silent (SNP) | VAF 379/380 reads (100%) | catalogued as rs1213957182; called by muse, mutect2, varscan2
- PLEC | c.12162C>T p.S4054= (on ENST00000322810 / NM_201380.4; = p.S3944= on NM_000445.5) | Silent (SNP) | VAF 433/978 reads (44%) | catalogued as rs782402718; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R37 | c.1419C>T p.S473= | Silent (SNP) | VAF 344/880 reads (39%) | called by muse, mutect2, varscan2
- PRKCB | c.1683C>T p.P561= | Silent (SNP) | VAF 191/191 reads (100%) | called by muse, mutect2, varscan2
- RASGEF1B | c.846A>T p.R282= | Silent (SNP) | VAF 141/141 reads (100%) | called by muse, mutect2, varscan2
- ROS1 | c.1575T>C p.F525= | Silent (SNP) | VAF 337/668 reads (50%) | called by muse, mutect2, varscan2
- RPA1 | c.1702C>A p.R568= | Silent (SNP) | VAF 104/104 reads (100%) | called by muse, mutect2, varscan2
- RRP36 | c.633C>T p.F211= | Silent (SNP) | VAF 195/431 reads (45%) | called by muse, mutect2, varscan2
- SGO2 | c.2055C>G p.T685= | Silent (SNP) | VAF 75/278 reads (27%) | called by muse, mutect2, varscan2
- SLC6A17 | c.1017C>A p.I339= | Silent (SNP) | VAF 295/680 reads (43%) | catalogued as COSV58996635; called by muse, mutect2, varscan2
- SNRNP200 | c.5346G>A p.S1782= | Silent (SNP) | VAF 270/401 reads (67%) | catalogued as rs756239767, COSV60493952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX27 | c.1542C>T p.F514= | Silent (SNP) | VAF 224/458 reads (49%) | catalogued as rs761223156, COSV64325782; called by muse, mutect2, varscan2
- SUZ12 | c.684G>T p.P228= | Silent (SNP) | VAF 243/528 reads (46%) | called by muse, mutect2, varscan2
- TFEB | c.1332G>C p.P444= | Silent (SNP) | VAF 433/886 reads (49%) | called by muse, mutect2, varscan2
- TMC8 | c.285C>A p.L95= | Silent (SNP) | VAF 195/839 reads (23%) | called by muse, mutect2, varscan2
- TMCC1 | c.300A>G p.T100= | Silent (SNP) | VAF 214/818 reads (26%) | called by muse, mutect2, varscan2
- TRIO | c.6384A>G p.L2128= | Silent (SNP) | VAF 44/422 reads (10%) | called by muse, mutect2, varscan2
- TUBA3E | c.1224C>T p.Y408= | Silent (SNP) | VAF 145/658 reads (22%) | catalogued as rs574854736; called by muse, mutect2
- UNC79 | c.6288G>T p.P2096= (on ENST00000393151 / NM_001346218.2; = p.P1919= on NM_020818.5) | Silent (SNP) | VAF 315/316 reads (100%) | catalogued as rs753101383, COSV56380645; called by muse, mutect2, varscan2
- USP19 | c.1338A>T p.T446= | Silent (SNP) | VAF 36/408 reads (9%) | called by muse, mutect2
- VEGFC | c.399A>G p.P133= | Silent (SNP) | VAF 182/182 reads (100%) | called by muse, mutect2, varscan2
- YARS2 | c.192C>T p.L64= | Silent (SNP) | VAF 765/766 reads (100%) | called by muse, mutect2, varscan2
- ZNF425 | c.240G>A p.R80= | Silent (SNP) | VAF 117/117 reads (100%) | called by muse, mutect2, varscan2
- ZNF727 | c.1149G>T p.L383= | Silent (SNP) | VAF 198/198 reads (100%) | called by muse, mutect2, varscan2
- ZNF814 | c.1683C>A p.G561= | Silent (SNP) | VAF 272/526 reads (52%) | called by muse, mutect2, varscan2
- FRRS1L | c.-58C>T | 5'UTR (SNP) | VAF 243/398 reads (61%) | catalogued as rs1280023187; called by muse, mutect2, varscan2
- HBS1L | c.430+2480C>T | Intron (SNP) | VAF 76/336 reads (23%) | catalogued as rs1442253987; called by muse, mutect2, varscan2
- MACF1 | c.15832-11630C>T | Intron (SNP) | VAF 288/289 reads (100%) | called by muse, mutect2, varscan2
- NSUN4 | c.94-1290C>G | Intron (SNP) | VAF 237/238 reads (100%) | called by muse, mutect2, varscan2
- SCAI | c.99-9999C>T | Intron (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- SLC25A1P5 | n.199C>T | RNA (SNP) | VAF 155/300 reads (52%) | called by muse, mutect2, varscan2
- TMEM99 | n.823C>T | RNA (SNP) | VAF 312/602 reads (52%) | catalogued as rs191706937; called by muse, mutect2, varscan2
